Gene-level copy-number profile of tumor specimen TCGA-25-2399-01A from TCGA case TCGA-25-2399, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 80.4 years (29,373 days).
Specimen TCGA-25-2399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.bf4172d6-d044-4dca-9e8b-a44a7a24ab4a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-2399-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a587abd-3acb-473e-a67d-3f1a200f292b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 137; copy number 2: 13,240; copy number 3: 7,819; copy number 4: 34,409; copy number 5: 331; copy number 6: 2,113; copy number 7: 2; copy number 8: 845; copy number 9: 491; copy number 10: 103; copy number 12: 142; copy number 14: 81; copy number 15: 60; copy number 19: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-25-2399-01A-01D-0704-01): tumor purity 0.84, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:31,008,497–31,538,211, 14 genes (within-gene range 0–2): AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P.
- chr19:37,312,837–37,369,365, 1 gene (within-gene range 0–6): ZNF875.
- chr19:37,337,236–37,549,171, 9 genes: AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 894 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:3,840,528–15,932,294, 292 genes, copy number 10–15 (broad region; genes not listed).
- chr19:6,887,566–10,713,437, 205 genes, copy number 9–19 (broad region; genes not listed).
- chr19:10,718,404–10,718,503, 1 gene, copy number 9: MIR638.
- chr19:11,420,604–15,419,141, 236 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr19:20,416,514–24,129,968, 160 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 137. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
